Somatic mutation profile of tumor specimen CDDP-ABKU-TTP2-A (aliquot CDDP-ABKU-TTP2-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABKU, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 79 years.
Specimen CDDP-ABKU-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72c2cf53-9379-4068-a8d1-7d78c1b4a920.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABKU-NB1-A (Blood Derived Normal), aliquot CDDP-ABKU-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/715062fa-ced1-471a-a3a9-9d3044d13644

The open-access MAF lists 409 somatic variants for this specimen: 291 protein-altering or splice-affecting, 71 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 247, Silent 71, Intron 24, Nonsense Mutation 18, Frame Shift Del 16, RNA 11, 5'Flank 6, Splice Site 5, 3'UTR 3, 5'UTR 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 70/357 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.540del p.N181Tfs*106 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | catalogued as rs1131690939; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A1BG | c.215T>A p.L72H | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54053054; called by muse, mutect2
- AARS2 | c.2531T>G p.L844R | Missense Mutation (SNP) | VAF 84/423 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV55117096; called by muse, mutect2, varscan2
- ABCC6 | c.2152G>T p.D718Y | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV52746599; called by muse, mutect2, varscan2
- ACKR3 | c.203T>A p.V68E | Missense Mutation (SNP) | VAF 76/480 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV56023221; called by muse, mutect2, varscan2
- ADAMTS16 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 67/263 reads (25%) | catalogued as COSV57003528; called by muse, mutect2, varscan2
- ADAMTSL3 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54464308; called by muse, mutect2, varscan2
- ADCY5 | c.2918G>T p.G973V | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV59202986; called by muse, mutect2, varscan2
- ADGRA1 | c.1345del p.R449Afs*88 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | catalogued as COSV66927805; called by mutect2, pindel, varscan2
- ADGRL3 | c.2208G>T p.M736I (on ENST00000506720 / NM_001322402.2; = p.M668I on NM_015236.6) | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV72231662; called by muse, mutect2, varscan2
- ADGRL3 | c.4089G>T p.E1363D (on ENST00000506720 / NM_001322402.2; = p.E1252D on NM_015236.6) | Missense Mutation (SNP) | VAF 89/527 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.023); catalogued as COSV72231663; called by muse, mutect2, varscan2
- AKAP11 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV50300335; called by muse, mutect2, varscan2
- ALDH7A1 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs781779462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER3 | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as COSV58469216, COSV58470670; called by muse, mutect2, varscan2
- ANKRD2 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1348679677; called by muse, mutect2, varscan2
- ANKRD45 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 14/264 reads (5%) | catalogued as COSV60962314; called by muse, mutect2
- APOB | c.10535C>A p.T3512N | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs145861016, COSV51948575; called by muse, mutect2, varscan2
- APOE | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 55/463 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV52985387; called by muse, mutect2, varscan2
- ARAP3 | c.4420A>T p.S1474C | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53353791; called by muse, mutect2, varscan2
- ARFGEF2 | c.3335G>T p.S1112I | Missense Mutation (SNP) | VAF 62/469 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV64214478; called by muse, mutect2, varscan2
- ARHGAP18 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV63765793; called by muse, mutect2, varscan2
- ARMC3 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as COSV53066175; called by muse, mutect2, varscan2
- ATP10B | c.3615G>T p.Q1205H | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59162108; called by muse, mutect2, varscan2
- BAIAP2L2 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1244490445; called by muse, mutect2, varscan2
- BMI1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as COSV64959121; called by muse, mutect2
- BOD1L1 | c.7663G>A p.E2555K | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV50044860; called by muse, mutect2
- BPIFB2 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV50069511; called by muse, mutect2, varscan2
- BRD2 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs554793680; called by muse, mutect2, varscan2
- C19orf84 | c.210C>A p.S70R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55741998; called by muse, mutect2, varscan2
- C3orf20 | c.1820C>G p.S607C | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.723); catalogued as rs563483009, COSV53788505; called by muse, mutect2, varscan2
- CA14 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as COSV52530297; called by muse, mutect2, varscan2
- CACNA1E | c.6113C>A p.S2038Y (on ENST00000367573 / NM_001205293.3; = p.S1995Y on NM_000721.4) | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV62413204; called by muse, mutect2, varscan2
- CAPN8 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954677210; called by muse, mutect2, varscan2
- CASP1 | c.895G>T p.V299L (on ENST00000436863 / NM_033292.4; = p.V278L on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV62057329; called by muse, mutect2, varscan2
- CCDC168 | c.19750C>A p.P6584T | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.66); catalogued as COSV59424859; called by muse, mutect2, varscan2
- CCER1 | c.699C>A p.N233K | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV62646126, COSV62648331; called by muse, mutect2, varscan2
- CD22 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as COSV50063229; called by muse, mutect2, varscan2
- CDC42BPG | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs760377383, COSV61348786; called by muse, mutect2, varscan2
- CEP170B | c.1072G>T p.G358C (on ENST00000453495; = p.G287C on NM_015005.3) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV69026247; called by muse, mutect2
- CFAP52 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55348357; called by muse, mutect2, varscan2
- CFAP65 | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV58565419; called by muse, mutect2, varscan2
- CHN1 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV69298128; called by muse, mutect2, varscan2
- CNTNAP2 | c.3142del p.Q1048Rfs*55 | Frame Shift Del (DEL) | VAF 68/356 reads (19%) | catalogued as COSV100674465; called by pindel, varscan2
- COL20A1 | c.3774G>T p.E1258D | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV58925196; called by muse, mutect2, varscan2
- COL4A1 | c.4237G>C p.A1413P | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV65430522; called by muse, mutect2, varscan2
- CORIN | c.2078C>G p.S693C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56697444; called by muse, mutect2, varscan2
- CPA5 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV62569230, COSV62570532; called by muse, mutect2, varscan2
- CTNNA2 | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV58173470; called by muse, mutect2, varscan2
- CWC22 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55427806, COSV55431549; called by muse, mutect2, varscan2
- CWH43 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV56942833; called by muse, mutect2, varscan2
- CWH43 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56942845; called by muse, mutect2, varscan2
- CYLC1 | c.91A>C p.K31Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV61415074; called by mutect2, varscan2
- DCLK1 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | catalogued as COSV55204521; called by muse, varscan2
- DEFA6 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52406470; called by muse, mutect2, varscan2
- DENND5B | c.2254G>T p.V752L | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV60907049; called by muse, mutect2, varscan2
- DIP2A | c.497G>T p.W166L | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59484879; called by muse, mutect2, varscan2
- DISP3 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756496600, COSV53835194; called by muse, mutect2, varscan2
- DOCK1 | c.692A>T p.N231I | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54755382; called by muse, mutect2
- DTD1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66281613; called by muse, mutect2, varscan2
- EIPR1 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV66132382; called by muse, mutect2, varscan2
- ELMOD1 | c.528G>C p.M176I | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56195341; called by muse, mutect2, varscan2
- EMILIN1 | c.773T>A p.L258Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53156718; called by muse, mutect2, varscan2
- ENC1 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV56630816; called by mutect2, varscan2
- ENOX1 | c.731A>G p.K244R | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV54914290; called by muse, mutect2
- EPB41L2 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV61358152; called by muse, mutect2, varscan2
- EXO1 | c.2089A>C p.S697R | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62219226; called by muse, mutect2, varscan2
- EXOC6 | c.2352G>T p.K784N | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV53331260; called by muse, mutect2, varscan2
- FAF1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV65642939; called by muse, mutect2, varscan2
- FAM47B | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1229137762, COSV61456239; called by muse, mutect2
- FAT3 | c.1539C>A p.S513R | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53160696; called by muse, mutect2, varscan2
- FAT3 | c.1540C>A p.L514M | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as COSV53160723; called by muse, mutect2, varscan2
- FAT4 | c.11321A>T p.Q3774L | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV58703211; called by muse, mutect2, varscan2
- FGF23 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 112/809 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52977629; called by muse, mutect2, varscan2
- FHOD1 | c.2434G>T p.V812L | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV50766970; called by muse, mutect2, varscan2
- FKTN | c.519G>T p.L173F | Missense Mutation (SNP) | VAF 87/413 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV56311642; called by muse, mutect2, varscan2
- FOXD4L1 | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 177/1032 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs1403391603; called by muse, mutect2, varscan2
- GAB4 | c.1147T>C p.C383R | Missense Mutation (SNP) | VAF 70/428 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV68754914; called by muse, mutect2, varscan2
- GALNT15 | c.686T>A p.V229E | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60219134; called by muse, mutect2, varscan2
- GAREM2 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as COSV68226170; called by muse, mutect2, varscan2
- GNG12 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV63973655; called by muse, mutect2, varscan2
- GPC6 | c.1197G>T p.W399C | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990168, COSV65531480; called by muse, mutect2, varscan2
- HIVEP1 | c.2197G>T p.G733C | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65104309; called by muse, mutect2, varscan2
- HJV | c.1136C>A p.A379E (on ENST00000336751 / NM_213653.4; = p.A266E on NM_145277.5) | Missense Mutation (SNP) | VAF 22/580 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as rs782737856; called by muse, mutect2
- HSPB3 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 65/384 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.165); catalogued as rs142691743; called by muse, mutect2, varscan2
- IFNA17 | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV69738270; called by muse, mutect2, varscan2
- INSYN2A | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.201); catalogued as COSV54755395; called by muse, mutect2, varscan2
- ITK | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs886060327, COSV101439961, COSV70062082; ClinVar: uncertain significance; called by muse, mutect2
- JPH3 | c.1235C>A p.A412D | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52472764; called by muse, mutect2, varscan2
- KCNF1 | c.956G>C p.R319P | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV54464136, COSV54465168; called by muse, mutect2, varscan2
- KCNJ16 | c.776A>G p.H259R | Missense Mutation (SNP) | VAF 80/473 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52256598; called by muse, mutect2, varscan2
- KCNT2 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV54102702; called by muse, mutect2, varscan2
- KNCN | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV53815428; called by muse, mutect2, varscan2
- KRT3 | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV58816856; called by muse, mutect2, varscan2
- KRTAP19-5 | c.166del p.R56Afs*22 | Frame Shift Del (DEL) | VAF 65/359 reads (18%) | catalogued as COSV61858824; called by mutect2, pindel, varscan2
- LAMA1 | c.6390C>A p.Y2130* | Nonsense Mutation (SNP) | VAF 156/499 reads (31%) | catalogued as COSV67542920; called by muse, mutect2, varscan2
- LAMA2 | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV70353390; called by muse, mutect2, varscan2
- LAMB3 | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV61918991; called by muse, mutect2, varscan2
- LILRB3 | c.1513C>T p.P505S (on ENST00000346401; = p.P493S on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV54444657, COSV99558359; called by muse, mutect2, varscan2
- LRP1B | c.6717C>A p.N2239K | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV67209683, COSV67262161; called by muse, mutect2, varscan2
- LRP4 | c.4579C>G p.R1527G | Missense Mutation (SNP) | VAF 91/426 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as COSV66133920, COSV66138058; called by muse, mutect2, varscan2
- LRRC66 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as COSV58636179; called by muse, varscan2
- LRRC8E | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60719383; called by muse, mutect2
- LRRK2 | c.1942G>A p.G648R | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54170346; called by muse, mutect2, varscan2
- LTBP1 | c.4645G>T p.E1549* (on ENST00000404816 / NM_206943.4; = p.E1223* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 26/223 reads (12%) | catalogued as COSV99698472; called by muse, mutect2, varscan2
- LTBR | c.1006G>T p.G336W | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57438742; called by muse, mutect2, varscan2
- LYAR | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV58643759; called by muse, mutect2, varscan2
- LZTR1 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.339); catalogued as COSV53150742; called by muse, mutect2, varscan2
- MAGEL2 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV58566886; called by muse, mutect2, varscan2
- MARCHF4 | c.836T>C p.M279T | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56107752; called by muse, varscan2
- MASP1 | c.1199C>A p.P400H | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1344067587, COSV51462994, COSV51464230; called by muse, mutect2, varscan2
- MROH2B | c.4262G>T p.R1421M | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV68188214; called by muse, mutect2, varscan2
- MS4A10 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57633037, COSV57633557; called by muse, mutect2, varscan2
- MUC16 | c.32400G>T p.L10800F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.181); catalogued as rs748022200, COSV67486536; called by muse, mutect2, varscan2
- MUC16 | c.26752G>T p.E8918* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV67486546; called by muse, mutect2, varscan2
- MYF5 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57356240; called by muse, mutect2
- MYH1 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV55446359; called by muse, mutect2, varscan2
- MYLK3 | c.1341G>C p.Q447H | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV67366215; called by muse, mutect2, varscan2
- MYO3B | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV58714127; called by muse, mutect2, varscan2
- NBEA | c.3193G>T p.E1065* | Nonsense Mutation (SNP) | VAF 35/218 reads (16%) | catalogued as COSV59814534; called by muse, mutect2, varscan2
- NCKAP5 | c.5101G>T p.D1701Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV58468196; called by muse, mutect2, varscan2
- NEB | c.4635G>T p.K1545N | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV51450296; called by muse, mutect2, varscan2
- NELL1 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV54337823; called by muse, mutect2
- NEXMIF | c.4189G>A p.G1397S | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV50080358; called by muse, mutect2, varscan2
- NLRP4 | c.2140del p.L714Sfs*5 | Frame Shift Del (DEL) | VAF 39/145 reads (27%) | catalogued as COSV100015572; called by mutect2, pindel, varscan2
- NLRP8 | c.141C>A p.N47K | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.091); catalogued as COSV52592535; called by muse, mutect2, varscan2
- NME8 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 38/170 reads (22%) | catalogued as rs981266761, COSV52254446, COSV99552967; called by muse, mutect2, varscan2
- NPY2R | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as COSV61529335; called by muse, mutect2, varscan2
- NR5A2 | c.1468C>G p.P490A (on ENST00000367362 / NM_205860.3; = p.P444A on NM_003822.5) | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV52656309; called by muse, mutect2
- NRXN1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs756908062, COSV68039489; called by muse, mutect2, varscan2
- NUDT14 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.956); catalogued as rs747955490, COSV59308469, COSV59312064; called by muse, mutect2, varscan2
- OASL | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759319882, COSV56566626; called by muse, mutect2
- OR13F1 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV58252463; called by muse, varscan2
- OR3A3 | c.712C>A p.R238S | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as COSV52168001, COSV52168316; called by muse, mutect2, varscan2
- OR4K5 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60003984, COSV60004319; called by muse, mutect2
- OR4N5 | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV61321134; called by muse, mutect2, varscan2
- OR4N5 | c.225C>A p.F75L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV61320255, COSV61321139; called by muse, mutect2, varscan2
- OR4P4 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs143338269, COSV58923294; called by muse, mutect2, varscan2
- OR4X1 | c.684G>T p.L228F | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV60723658; called by muse, mutect2, varscan2
- OR51E1 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV67810778; called by muse, mutect2, varscan2
- OR5B12 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); catalogued as rs139272006; called by muse, mutect2, varscan2
- OR5J2 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs757035260, COSV56622748; called by muse, mutect2, varscan2
- OR9G4 | c.918G>T p.Q306H | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57247884; called by muse, varscan2
- OSBPL2 | c.446G>C p.G149A (on ENST00000313733 / NM_144498.4; = p.G137A on NM_014835.4) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58219193; called by muse, mutect2, varscan2
- OSR2 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as COSV52558472; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.280C>A p.Q94K (on ENST00000374531 / NM_001037293.2; = p.Q92K on NM_007203.5) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.043); catalogued as COSV57130011; called by muse, mutect2, varscan2
- PANX3 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV52512577, COSV52513469; called by muse, mutect2, varscan2
- PCDH15 | c.2002G>T p.G668W | Missense Mutation (SNP) | VAF 77/467 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57256966, COSV57278999, COSV57411195; called by muse, mutect2, varscan2
- PCDHA4 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63545130; called by muse, mutect2, varscan2
- PCDHGA3 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV54011562; called by muse, mutect2, varscan2
- PKD1L2 | c.1273C>A p.L425M | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768712159, COSV61418732; called by muse, mutect2, varscan2
- PKHD1L1 | c.2899G>T p.E967* | Nonsense Mutation (SNP) | VAF 39/213 reads (18%) | catalogued as COSV65750464; called by muse, mutect2, varscan2
- POLR3C | c.464_465del p.H155Lfs*12 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs781950973; called by pindel, varscan2
- PPFIA4 | c.2380A>C p.M794L (on ENST00000447715; = p.M795L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55320055; called by muse, varscan2
- PPP1R15B | c.1837G>T p.G613W | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65816401; called by muse, varscan2
- PRDM11 | c.586C>T p.L196= (on ENST00000530656 / NM_001359633.1; = p.L162= on NM_001256695.1) | Splice Region (SNP) | VAF 14/60 reads (23%) | catalogued as rs368313733; called by muse, varscan2
- PRDM13 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 24/313 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65030523; called by muse, mutect2
- PTPRT | c.986C>A p.T329N | Missense Mutation (SNP) | VAF 69/431 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV61967747; called by muse, mutect2, varscan2
- RAB11FIP5 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV50255701; called by muse, mutect2, varscan2
- RAD18 | c.1286A>C p.E429A | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV53752255; called by muse, mutect2, varscan2
- RALGAPA2 | c.338T>C p.L113S | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52508074; called by muse, mutect2, varscan2
- RALYL | c.91del p.A31Qfs*18 | Frame Shift Del (DEL) | VAF 53/327 reads (16%) | catalogued as COSV101569206, COSV72820208; called by mutect2, pindel, varscan2
- RGS22 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV62666325; called by muse, mutect2, varscan2
- RIMBP2 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 49/235 reads (21%) | catalogued as COSV55478093, COSV55481546; called by muse, mutect2, varscan2
- RNASEH2B | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 65/369 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV60747524; called by muse, mutect2, varscan2
- RP1L1 | c.1648G>T p.G550W | Missense Mutation (SNP) | VAF 93/659 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV66759018; called by muse, mutect2, varscan2
- RRP36 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.247); catalogued as COSV55065503; called by muse, mutect2
- RTL1 | c.2119C>A p.P707T | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV66017348; called by muse, mutect2, varscan2
- RUNX1 | c.427G>T p.G143W (on ENST00000344691 / NM_001001890.3; = p.G170W on NM_001754.5) | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1210372, COSV55876267, COSV55877313, COSV55889031; called by muse, mutect2, varscan2
- RYR2 | c.6977G>A p.R2326Q | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773565555, COSV63685479; called by muse, mutect2
- SALL3 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as COSV73306402; called by muse, mutect2, varscan2
- SALL3 | c.1247C>G p.P416R | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs774910880, COSV73306032, COSV73306403; called by muse, mutect2, varscan2
- SH2D5 | c.529G>A p.G177S (on ENST00000444387 / NM_001103161.2; = p.G93S on NM_001103160.2) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as rs1297728014, COSV66707383; called by muse, mutect2, varscan2
- SMARCAD1 | c.2904G>T p.Q968H | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62775867; called by muse, mutect2, varscan2
- SP7 | c.887G>C p.C296S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV58191848; called by muse, mutect2, varscan2
- SPATA31A1 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1017446429; called by mutect2, varscan2
- SPEG | c.5693G>T p.R1898L | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV56677681; called by muse, mutect2, varscan2
- SPEG | c.8441C>A p.P2814H | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.319); catalogued as COSV56677689; called by muse, mutect2, varscan2
- SRGAP2 | c.2479G>A p.D827N (on ENST00000624873 / NM_001170637.4; = p.D828N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs782524607; called by muse, mutect2
- SST | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55031398; called by muse, mutect2, varscan2
- STPG1 | c.737+1G>A p.X246_splice (on ENST00000337248 / NM_001199013.2; = p.X199_splice on NM_178122.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as rs1387593559; called by muse, varscan2
- SUPT20H | c.1664G>T p.G555V (on ENST00000350612 / NM_001014286.3; = p.G556V on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV62246866, COSV62249169; called by muse, varscan2
- SVEP1 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV57045161; called by muse, varscan2
- TBC1D4 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100884533, COSV66487639; called by muse, mutect2, varscan2
- TCN2 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV53192680; called by muse, mutect2, varscan2
- TEK | c.288C>G p.I96M | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV66232285; called by muse, mutect2, varscan2
- TENM1 | c.4582C>A p.L1528M | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV64440441; called by muse, mutect2, varscan2
- TEX11 | c.1597G>A p.A533T (on ENST00000344304; = p.A518T on NM_031276.3) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV60237014; called by muse, mutect2, varscan2
- TEX15 | c.6883C>A p.P2295T (on ENST00000256246; = p.P2678T on NM_001350162.2) | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV56343837, COSV56352050; called by muse, mutect2, varscan2
- TM6SF1 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV51945996; called by muse, mutect2, varscan2
- TNFRSF10D | c.764A>G p.H255R | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.162); catalogued as COSV57037428; called by muse, mutect2, varscan2
- TNFRSF21 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 28/288 reads (10%) | catalogued as COSV57284572; called by muse, mutect2
- TNRC18 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs772830616, COSV68087913; called by mutect2, varscan2
- TNS1 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907813420, COSV50750557; called by muse, mutect2, varscan2
- TRMT2B | c.93G>T p.W31C | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV58620696; called by muse, mutect2, varscan2
- TTLL10 | c.989A>C p.E330A (on ENST00000379289 / NM_001130045.2; = p.E257A on NM_153254.3) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.695); catalogued as COSV64960991; called by muse, mutect2, varscan2
- UBE3C | c.3229G>C p.A1077P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV61955213; called by muse, mutect2, varscan2
- UBR2 | c.2355G>T p.Q785H | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV65752035; called by muse, mutect2
- URGCP-MRPS24 | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 14/119 reads (12%) | catalogued as COSV58183010; called by muse, mutect2, varscan2
- USP7 | c.3137G>T p.G1046V | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV61216919; called by muse, mutect2, varscan2
- UTY | c.2252A>C p.H751P | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as COSV58869632, COSV58871748; called by muse, mutect2, varscan2
- VCAN | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV54114183; called by muse, mutect2, varscan2
- WFS1 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs143084511, CM015265, COSV56987285; called by muse, mutect2, varscan2
- WHRN | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 57/279 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as COSV54334086; called by muse, mutect2, varscan2
- WNK2 | c.3670G>C p.A1224P | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52956602; called by muse, mutect2, varscan2
- XIRP2 | c.3109A>G p.I1037V (on ENST00000628543; = p.I1212V on NM_152381.6) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs375709480; called by muse, mutect2, varscan2
- XIRP2 | c.5815A>T p.I1939F (on ENST00000628543; = p.I2114F on NM_152381.6) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV54727388; called by muse, mutect2
- ZAR1L | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV61526286; called by muse, mutect2, varscan2
- ZFP64 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 37/292 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.15); catalogued as COSV53802952; called by muse, mutect2, varscan2
- ZIM2 | c.605G>T p.R202M | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55644137; called by muse, mutect2, varscan2
- ZNF10 | c.1360A>G p.T454A | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV50213109, COSV50213133; called by muse, mutect2, varscan2
- ZNF148 | c.739A>T p.R247* | Nonsense Mutation (SNP) | VAF 33/172 reads (19%) | catalogued as COSV62307025; called by muse, mutect2, varscan2
- ZNF326 | c.66G>T p.M22I | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV61036136; called by muse, mutect2, varscan2
- ZNF358 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV51179290; called by muse, mutect2, varscan2
- ZNF516 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV71587521; called by muse, mutect2, varscan2
- ZNF585A | c.862C>T p.H288Y (on ENST00000292841 / NM_001288800.2; = p.H233Y on NM_152655.3) | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53066382; called by muse, mutect2, varscan2
- ZNF775 | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV61614173; called by muse, mutect2, varscan2
- ZNF790 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 42/367 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV63213115; called by muse, mutect2, varscan2
- ADAMTS16 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ADGRA1 | c.1144T>A p.F382I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); called by mutect2, varscan2
- ADNP | c.937A>G p.N313D | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.098); called by muse, mutect2
- AHNAK2 | c.10111C>A p.Q3371K | Missense Mutation (SNP) | VAF 75/454 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ANK2 | c.3900G>T p.W1300C | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK2 | c.4647del p.F1549Lfs*11 | Frame Shift Del (DEL) | VAF 34/202 reads (17%) | called by mutect2, pindel, varscan2
- AQP12B | c.439G>T p.V147L (on ENST00000621682; = p.V159L on NM_001102467.2) | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.05); called by muse, varscan2
- ARMC3 | c.507C>G p.N169K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP11C | c.977_978insT p.W326Cfs*3 | Frame Shift Ins (INS) | VAF 19/76 reads (25%) | called by mutect2, pindel*, varscan2
- ATP2B2 | c.1161del p.K388Rfs*5 (on ENST00000352432; = p.K354Rfs*5 on NM_001683.5) | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- BCO2 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 127/612 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- C1QTNF9 | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CACNA1B | c.3585del p.F1196Lfs*4 | Frame Shift Del (DEL) | VAF 24/174 reads (14%) | called by mutect2, pindel, varscan2
- CEP192 | c.4782G>T p.W1594C | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP78 | c.1631G>T p.G544V (on ENST00000424347 / NM_001349840.2; = p.G545V on NM_032171.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CNBD1 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- COL5A3 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRACD | c.923_924insGAGGGAGCGGAGGGAGAG p.R308_E309insRERRES | In Frame Ins (INS) | VAF 7/68 reads (10%) | called by mutect2, pindel
- DUSP4 | c.561del p.T188Pfs*39 | Frame Shift Del (DEL) | VAF 26/190 reads (14%) | called by mutect2, pindel, varscan2
- EPS8L3 | c.1628_1630del p.F543del (on ENST00000361965 / NM_133181.4; = p.F513del on NM_024526.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 29/154 reads (19%) | called by mutect2, pindel, varscan2
- ERC1 | c.2194G>T p.E732* (on ENST00000360905 / NM_178040.4; = p.E704* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, varscan2
- FAM153A | c.472A>T p.N158Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FAM153B | c.703A>T p.N235Y (on ENST00000253490; = p.N158Y on NM_001265615.1) | Missense Mutation (SNP) | VAF 29/508 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2
- FBXO16 | c.100-1G>T p.X34_splice | Splice Site (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- FLNA | c.5409G>C p.E1803D (on ENST00000369850 / NM_001110556.2; = p.E1795D on NM_001456.3) | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- FLNC | c.3891_3892del p.A1298Qfs*33 | Frame Shift Del (DEL) | VAF 38/219 reads (17%) | called by mutect2, pindel, varscan2
- FREM3 | c.4771C>A p.R1591S | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- HMCN1 | c.4637del p.P1546Lfs*15 | Frame Shift Del (DEL) | VAF 26/250 reads (10%) | called by mutect2, varscan2
- HMCN2 | c.10355G>T p.G3452V | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFI44 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 37/175 reads (21%) | called by muse, mutect2, varscan2
- ITIH5 | c.2299G>T p.G767C | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF2A | c.1173dup p.Q392Tfs*17 | Frame Shift Ins (INS) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
- LILRA6 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2
- LILRB1 | c.1421C>A p.A474E (on ENST00000427581; = p.A438E on NM_001081637.2) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LRRC53 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- LZTS1 | c.967A>T p.K323* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- MALRD1 | c.5678G>T p.G1893V | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- MARVELD2 | c.1603A>T p.K535* | Nonsense Mutation (SNP) | VAF 15/292 reads (5%) | called by muse, mutect2
- MYO1B | c.1983-1G>T p.X661_splice | Splice Site (SNP) | VAF 32/180 reads (18%) | called by mutect2, varscan2
- MYOZ2 | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.019); called by muse, mutect2
- NEK10 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NOL11 | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PAX5 | c.681_682delinsA p.D227Efs*51 | Frame Shift Del (DEL) | VAF 31/168 reads (18%) | called by pindel, varscan2*
- PCARE | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH11Y | c.2614C>T p.P872S (on ENST00000400457 / NM_032973.2; = p.P861S on NM_032971.3) | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- PCDHA8 | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 153/801 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHGA6 | c.567del p.K190Sfs*41 | Frame Shift Del (DEL) | VAF 15/140 reads (11%) | called by mutect2, varscan2
- PDE6C | c.1119+1G>T p.X373_splice | Splice Site (SNP) | VAF 60/385 reads (16%) | called by muse, mutect2, varscan2
- PPP3CB | c.1106A>G p.K369R | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- PPP4R4 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- PSG11 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRT | c.2601del p.A868Pfs*14 | Frame Shift Del (DEL) | VAF 39/338 reads (12%) | called by mutect2, varscan2
- RALGPS2 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2
- RGCC | c.406+2T>A p.X136_splice | Splice Site (SNP) | VAF 20/124 reads (16%) | called by muse, varscan2
- SLC22A15 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SPATA31A1 | c.2100G>T p.E700D | Missense Mutation (SNP) | VAF 66/878 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, varscan2
- SYTL4 | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TACO1 | c.543C>G p.H181Q | Missense Mutation (SNP) | VAF 89/474 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TBX22 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- TCEAL6 | c.331A>C p.K111Q | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TCP10L2 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- THBS2 | c.1043C>A p.T348N | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- TPTE | c.683G>T p.R228M (on ENST00000618007 / NM_199261.4; = p.R210M on NM_199259.4) | Missense Mutation (SNP) | VAF 42/662 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TRAJ43 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 52/207 reads (25%) | called by muse, mutect2, varscan2
- TRIM51GP | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TRIM64 | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); called by mutect2, varscan2
- TTF2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TTLL8 | c.2524G>A p.G842R | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF493 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF592 | c.1643C>G p.A548G | Missense Mutation (SNP) | VAF 94/865 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF729 | c.2878G>T p.G960W | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF729 | c.3233G>T p.C1078F | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF729 | c.3234T>G p.C1078W | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACKR3 | c.204G>A p.V68= | Silent (SNP) | VAF 76/478 reads (16%) | catalogued as COSV56023232; called by muse, mutect2, varscan2
- ALPI | c.51C>T p.S17= | Silent (SNP) | VAF 71/296 reads (24%) | catalogued as COSV55015827; called by muse, varscan2
- ARHGEF38 | c.927T>C p.S309= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV70365005; called by muse, mutect2, varscan2
- BHLHA9 | c.189C>T p.S63= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs1354047936, COSV66953786; called by muse, varscan2
- BMS1 | c.1656A>T p.S552= | Silent (SNP) | VAF 44/301 reads (15%) | catalogued as COSV65735142; called by muse, mutect2, varscan2
- BRINP3 | c.1299G>A p.V433= | Silent (SNP) | VAF 40/553 reads (7%) | catalogued as rs767635698; called by muse, mutect2
- C8orf88 | c.81G>T p.V27= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs571494044; called by muse, mutect2, varscan2
- CAPN8 | c.1182G>T p.V394= | Silent (SNP) | VAF 56/138 reads (41%) | called by muse, varscan2
- CCDC166 | c.345C>A p.L115= | Silent (SNP) | VAF 48/260 reads (18%) | catalogued as COSV72638881; called by muse, mutect2, varscan2
- CHST1 | c.633C>G p.P211= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs898108901, COSV57325168; called by muse, mutect2, varscan2
- CPS1 | c.2787G>A p.R929= | Silent (SNP) | VAF 79/402 reads (20%) | called by muse, mutect2, varscan2
- DCST1 | c.618C>T p.G206= | Silent (SNP) | VAF 156/408 reads (38%) | catalogued as COSV55062319; called by muse, mutect2, varscan2
- DNAH9 | c.7068G>C p.L2356= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as rs1442040739, COSV52370708; called by muse, mutect2, varscan2
- EEF2 | c.1653G>A p.E551= | Silent (SNP) | VAF 29/183 reads (16%) | catalogued as rs1411866322, COSV58580650; called by muse, mutect2, varscan2
- ENOX1 | c.729C>A p.R243= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV54914310; called by muse, mutect2
- FBXO11 | c.2208T>C p.C736= (on ENST00000403359 / NM_001190274.2; = p.C652= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/299 reads (14%) | catalogued as COSV52285673; called by muse, mutect2, varscan2
- FCRL2 | c.454C>T p.L152= | Silent (SNP) | VAF 29/765 reads (4%) | catalogued as COSV63834845; called by muse, mutect2
- GTF3C5 | c.1443G>C p.T481= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as rs200561021, COSV100565221; called by muse, mutect2
- HEPHL1 | c.2274C>T p.H758= | Silent (SNP) | VAF 21/202 reads (10%) | catalogued as rs373693837; called by muse, mutect2, varscan2
- HKDC1 | c.174G>T p.T58= | Silent (SNP) | VAF 38/218 reads (17%) | catalogued as COSV63578876; called by muse, mutect2, varscan2
- IGSF9B | c.135C>T p.C45= | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as rs374604489; called by muse, mutect2, varscan2
- IRF8 | c.732C>T p.P244= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as rs28368113, COSV51900068; called by muse, mutect2, varscan2
- ITGA2B | c.528C>A p.P176= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as rs544126537, COSV52231674; called by muse, mutect2, varscan2
- ITGB4 | c.4284C>T p.S1428= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- JPH3 | c.1236C>G p.A412= | Silent (SNP) | VAF 23/194 reads (12%) | catalogued as rs367695644, COSV52472773; called by muse, mutect2, varscan2
- KIR3DL3 | c.345C>A p.I115= | Silent (SNP) | VAF 28/106 reads (26%) | called by muse, varscan2
- KRT32 | c.384C>A p.I128= | Silent (SNP) | VAF 45/273 reads (16%) | catalogued as COSV56787735, COSV99862925; called by muse, mutect2, varscan2
- LINGO1 | c.972C>T p.A324= | Silent (SNP) | VAF 29/266 reads (11%) | catalogued as rs550891976; called by muse, mutect2, varscan2
- LUC7L | c.636C>G p.G212= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as COSV53460245; called by muse, mutect2, varscan2
- MARCHF11 | c.417C>A p.P139= | Silent (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- MEFV | c.531C>A p.T177= | Silent (SNP) | VAF 58/314 reads (18%) | catalogued as COSV54826202; called by muse, mutect2, varscan2
- MPEG1 | c.24C>A p.I8= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV57094090; called by muse, mutect2
- MROH2A | c.3276C>A p.A1092= | Silent (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- MXRA5 | c.6447G>T p.T2149= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs760712668, COSV54246387, COSV99477297; called by muse, mutect2, varscan2
- MYH7 | c.5400C>A p.A1800= | Silent (SNP) | VAF 80/544 reads (15%) | catalogued as COSV62525110; called by muse, mutect2, varscan2
- MYH7 | c.4500G>T p.R1500= | Silent (SNP) | VAF 60/409 reads (15%) | catalogued as COSV62517394, COSV62522791; called by muse, mutect2, varscan2
- NCOA7 | c.1047A>G p.V349= | Silent (SNP) | VAF 39/265 reads (15%) | catalogued as rs761684578, COSV57658810; called by muse, mutect2, varscan2
- NEFL | c.750C>A p.T250= | Silent (SNP) | VAF 67/509 reads (13%) | catalogued as COSV55338171; called by muse, mutect2, varscan2
- NEUROG1 | c.519G>T p.L173= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV59082946; called by muse, mutect2, varscan2
- NKX2-3 | c.393C>A p.A131= | Silent (SNP) | VAF 62/368 reads (17%) | catalogued as COSV60728535, COSV60729201; called by muse, mutect2, varscan2
- NLRP4 | c.1968G>C p.V656= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs775286607, COSV56721194; called by muse, mutect2, varscan2
- NOX5 | c.1584G>C p.L528= | Silent (SNP) | VAF 25/190 reads (13%) | catalogued as COSV52994478; called by muse, mutect2, varscan2
- NPAP1 | c.1104C>A p.T368= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV61503892, COSV61510340; called by muse, mutect2, varscan2
- NUP98 | c.1272A>C p.P424= | Silent (SNP) | VAF 59/251 reads (24%) | catalogued as COSV61437377; called by muse, mutect2, varscan2
- NWD1 | c.933C>T p.T311= | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- OR10H1 | c.237G>T p.P79= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV58472317, COSV58472669; called by muse, mutect2, varscan2
- OR2C3 | c.804C>T p.S268= | Silent (SNP) | VAF 78/496 reads (16%) | catalogued as COSV63575966; called by muse, mutect2, varscan2
- OR2T27 | c.738G>T p.V246= | Silent (SNP) | VAF 121/351 reads (34%) | catalogued as rs934661463; called by muse, mutect2, varscan2
- OR5H14 | c.513C>A p.S171= | Silent (SNP) | VAF 34/187 reads (18%) | called by muse, mutect2, varscan2
- OR8A1 | c.912G>A p.L304= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV52509734; called by muse, varscan2
- PAGE5 | c.18C>T p.A6= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as rs375197350; called by muse, mutect2, varscan2
- PCDH11Y | c.1857T>C p.G619= (on ENST00000400457 / NM_032973.2; = p.G608= on NM_032971.3) | Silent (SNP) | VAF 21/260 reads (8%) | called by muse, mutect2
- PIK3R5 | c.1650G>A p.R550= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as rs1344170077, COSV52657602; called by muse, mutect2, varscan2
- RGS20 | c.555C>A p.P185= (on ENST00000297313 / NM_170587.4; = p.P38= on NM_003702.4) | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV52017096, COSV52021288; called by muse, mutect2, varscan2
- RXFP1 | c.582T>C p.F194= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV57054998; called by muse, mutect2, varscan2
- SEC16B | c.303A>G p.P101= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV57629232; called by muse, mutect2, varscan2
- SEZ6L | c.579C>A p.V193= | Silent (SNP) | VAF 48/254 reads (19%) | catalogued as COSV50678992; called by muse, mutect2, varscan2
- SLC45A1 | c.1035G>T p.T345= | Silent (SNP) | VAF 86/347 reads (25%) | catalogued as COSV57096777, COSV57099156; called by muse, mutect2, varscan2
- SLC5A8 | c.219C>A p.G73= | Silent (SNP) | VAF 63/299 reads (21%) | catalogued as COSV73311084; called by muse, mutect2, varscan2
- SLIT3 | c.1851C>T p.I617= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as rs533167769, COSV60628887; called by muse, mutect2, varscan2
- SSC5D | c.879G>T p.A293= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV52701837, COSV99219880; called by muse, mutect2, varscan2
- SYT8 | c.711G>T p.P237= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV53290775, COSV99425670; called by mutect2, varscan2
- TCN1 | c.753C>T p.L251= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV57252029; called by muse, mutect2, varscan2
- TRDV3 | c.270C>A p.T90= | Silent (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- TRIM10 | c.387C>A p.T129= | Silent (SNP) | VAF 20/117 reads (17%) | called by muse, varscan2
- TRPM6 | c.1746C>G p.V582= | Silent (SNP) | VAF 44/206 reads (21%) | catalogued as COSV62520261; called by muse, mutect2, varscan2
- UNC13C | c.4947G>A p.Q1649= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV52913265; called by muse, mutect2, varscan2
- ZAR1L | c.456G>A p.A152= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs1295859499, COSV61525425; called by muse, mutect2, varscan2
- ZFP41 | c.21A>G p.R7= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV58088162; called by muse, mutect2, varscan2
- ZNF280B | c.348T>C p.I116= | Silent (SNP) | VAF 34/193 reads (18%) | catalogued as COSV64529496; called by muse, mutect2, varscan2
- ZNF875 | c.264G>T p.G88= | Silent (SNP) | VAF 31/298 reads (10%) | catalogued as COSV60993240, COSV60994585; called by muse, mutect2, varscan2
- AC009093.3 | chr16:29102042 C>A | 3'Flank (SNP) | VAF 29/188 reads (15%) | called by muse, mutect2, varscan2
- AC068633.1 | n.152C>A | RNA (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1776C>A | RNA (SNP) | VAF 63/554 reads (11%) | called by muse, mutect2, varscan2
- ACSL6 | chr5:132011884 C>A | 5'Flank (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- ASS1 | c.421-13G>C | Intron (SNP) | VAF 49/230 reads (21%) | called by muse, mutect2, varscan2
- AVPR1A | c.*2011del | 3'UTR (DEL) | VAF 25/203 reads (12%) | called by mutect2, pindel, varscan2
- BIRC8 | n.1486C>T | RNA (SNP) | VAF 20/222 reads (9%) | catalogued as rs377022781, COSV58843147; called by muse, mutect2
- BRWD1 | chr21:39314394 G>T | 5'Flank (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- CCNYL2 | n.1057G>A | RNA (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- CTDP1 | chr18:79679493 G>T | 5'Flank (SNP) | VAF 63/309 reads (20%) | called by muse, mutect2, varscan2
- DAB1 | c.597+45G>T | Intron (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- DDX11 | c.480+134G>T | Intron (SNP) | VAF 79/478 reads (17%) | called by muse, mutect2, varscan2
- DTWD1 | c.264+1353C>T | Intron (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- EPN3 | c.*68G>T | 3'UTR (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- EPOR | c.251+82C>T | Intron (SNP) | VAF 26/355 reads (7%) | catalogued as rs1214629306; called by muse, mutect2
- ETFA | c.269-35A>T | Intron (SNP) | VAF 81/424 reads (19%) | called by muse, mutect2, varscan2
- EYA3 | c.-27A>G | 5'UTR (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- FOLH1B | n.1198C>A | RNA (SNP) | VAF 38/252 reads (15%) | called by muse, mutect2, varscan2
- GAS8 | c.90+1517G>T | Intron (SNP) | VAF 39/168 reads (23%) | catalogued as rs763110146, COSV51942469; called by muse, mutect2, varscan2
- HNF1A | c.1108-48C>A | Intron (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- HNF1A | c.1108-47C>A | Intron (SNP) | VAF 25/277 reads (9%) | called by muse, mutect2
- IQCN | c.2616+228G>T | Intron (SNP) | VAF 31/161 reads (19%) | catalogued as COSV66576883; called by muse, mutect2, varscan2
- ITGA7 | chr12:55712254 T>C | 5'Flank (SNP) | VAF 40/208 reads (19%) | called by muse, mutect2, varscan2
- LAMTOR4 | c.203-153A>G | Intron (SNP) | VAF 36/136 reads (26%) | catalogued as rs1325122308; called by muse, mutect2, varscan2
- LAT | c.581-18G>T | Intron (SNP) | VAF 7/43 reads (16%) | catalogued as rs540294882; called by muse, mutect2, varscan2
- LHX1 | c.-413C>A | 5'UTR (SNP) | VAF 34/186 reads (18%) | called by muse, mutect2, varscan2
- LRRC29 | c.-134-281G>T | Intron (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- MFRP | chr11:119345563 G>C | 5'Flank (SNP) | VAF 66/324 reads (20%) | catalogued as CD052468, COSV64129114; called by muse, mutect2, varscan2
- MIR520E | n.7G>T | RNA (SNP) | VAF 48/208 reads (23%) | called by muse, mutect2, varscan2
- MLLT10 | c.1699+6268A>T | Intron (SNP) | VAF 13/110 reads (12%) | catalogued as COSV57002585; called by muse, mutect2, varscan2
- MORF4 | n.602G>T | RNA (SNP) | VAF 71/348 reads (20%) | called by muse, mutect2, varscan2
- OR3A4P | n.1139G>T | RNA (SNP) | VAF 43/265 reads (16%) | called by muse, mutect2, varscan2
- PRSS1 | c.200+11_200+12del | Intron (DEL) | VAF 36/189 reads (19%) | called by pindel, varscan2
- RNA5-8SP2 | chr16:34159450 C>A | 5'Flank (SNP) | VAF 16/104 reads (15%) | catalogued as rs796748335; called by muse, mutect2, varscan2
- RPL23 | c.13+181T>A | Intron (SNP) | VAF 38/287 reads (13%) | called by muse, mutect2, varscan2
- SPOCD1 | c.2534+123G>T | Intron (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- SPOCD1 | c.2534+122G>T | Intron (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- SSPOP | n.8444G>A | RNA (SNP) | VAF 19/81 reads (23%) | catalogued as rs751082630, COSV65135478; called by muse, mutect2, varscan2
- TARS2 | c.387+46G>A | Intron (SNP) | VAF 97/322 reads (30%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1033G>T | Intron (SNP) | VAF 24/428 reads (6%) | called by muse, mutect2
- TCP11X2 | c.710-41del | Intron (DEL) | VAF 40/250 reads (16%) | called by mutect2, pindel, varscan2
- TOP1MT | c.361-1442C>T | Intron (SNP) | VAF 20/106 reads (19%) | catalogued as rs576421557; called by muse, mutect2, varscan2
- TPO | c.*100G>T | 3'UTR (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- TRIM29 | c.1334-365C>A | Intron (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.829C>A | RNA (SNP) | VAF 42/392 reads (11%) | called by muse, varscan2
- UBBP4 | n.785C>A | RNA (SNP) | VAF 163/916 reads (18%) | called by muse, varscan2
- VPS35 | c.2212-168A>G | Intron (SNP) | VAF 13/100 reads (13%) | called by mutect2, varscan2
